Somatic mutation profile of tumor specimen TCGA-AK-3465-01A (aliquot TCGA-AK-3465-01A-01W-0886-08) from TCGA case TCGA-AK-3465, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 71.8 years (26,232 days).
Specimen TCGA-AK-3465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 821c4590-62bb-47c9-93d7-37c78ee3f8c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3465-10A (Blood Derived Normal), aliquot TCGA-AK-3465-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d84a295-b565-454c-9980-93e4202b1632

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Frame Shift Ins 6, Silent 5, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs74821926, CM870084, CM890279, CM910022, COSV55735814; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.1656G>A p.W552* | Nonsense Mutation (SNP) | VAF 5/103 reads (5%) | catalogued as COSV53318371; called by muse, mutect2
- ASCC2 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57072516; called by muse, mutect2, varscan2
- ATP10D | c.3668C>T p.T1223I | Missense Mutation (SNP) | VAF 74/977 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1302821257, COSV56705052; called by muse, mutect2
- ATP1A3 | c.251C>T p.T84M (on ENST00000545399 / NM_001256214.2; = p.T71M on NM_152296.5) | Missense Mutation (SNP) | VAF 163/413 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57485231; called by muse, mutect2, varscan2
- C1QC | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65889349; called by muse, mutect2, varscan2
- CAAP1 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61700383; called by muse, mutect2, varscan2
- CRACD | c.1963dup p.R655Pfs*28 | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | catalogued as rs769175297; called by pindel, varscan2
- ELAPOR1 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64040109; called by muse, mutect2, varscan2
- FNIP1 | c.1480del p.A494Qfs*26 | Frame Shift Del (DEL) | VAF 86/307 reads (28%) | catalogued as COSV57195537; called by mutect2, pindel, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 20/120 reads (17%) | catalogued as rs749150409; called by mutect2, varscan2
- GTF3C2 | c.1130T>C p.F377S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53125401; called by muse, mutect2, varscan2
- IL12RB1 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as rs774754664, COSV74045445; called by muse, mutect2
- ITIH2 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as rs142420238; called by muse, mutect2, varscan2
- LZTS3 | c.542dup p.Q182Afs*7 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | catalogued as rs745647523; called by pindel, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | catalogued as rs777328830; called by mutect2, varscan2
- OR6Q1 | c.239T>G p.V80G | Missense Mutation (SNP) | VAF 258/478 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV56932513; called by muse, mutect2, varscan2
- PCDHGB6 | c.2126T>A p.L709Q | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53914164; called by muse, mutect2, varscan2
- PLXNA4 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs143690954, COSV58111460; called by muse, mutect2, varscan2
- POLE | c.4647dup p.K1550Qfs*11 | Frame Shift Ins (INS) | VAF 7/73 reads (10%) | catalogued as rs754220952; ClinVar: uncertain significance; called by mutect2, pindel
- PROX1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV54776823; called by muse, mutect2, varscan2
- PRPF40B | c.143C>T p.A48V (on ENST00000380281; = p.A42V on NM_012272.3) | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs149751647; called by muse, mutect2
- SAMD4B | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV58750516; called by muse, mutect2, varscan2
- SIPA1L3 | c.5093C>T p.P1698L | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as rs765717001, COSV55910444; called by muse, mutect2, varscan2
- SLC45A1 | c.1832A>G p.Y611C | Missense Mutation (SNP) | VAF 76/105 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754751877, COSV57093663; called by muse, mutect2, varscan2
- WDR27 | c.2130G>T p.R710S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs749053028, COSV61205454; called by muse, mutect2, varscan2
- BBOF1 | c.777_781del p.L259Ffs*8 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by pindel, varscan2
- CAPS | c.267dup p.M90Hfs*63 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by pindel, varscan2
- DNAH10 | c.12936G>A p.K4312= (on ENST00000409039; = p.K4251= on NM_207437.3) | Silent (SNP) | VAF 36/303 reads (12%) | catalogued as COSV53018893; called by muse, mutect2, varscan2
- ELFN2 | c.708C>T p.N236= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs149957183; called by muse, mutect2, varscan2
- LAMA4 | c.2532G>A p.V844= (on ENST00000230538 / NM_001105206.3; = p.V837= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV57893175; called by muse, mutect2
- TMC2 | c.1668C>T p.N556= | Silent (SNP) | VAF 118/301 reads (39%) | catalogued as rs144876435; called by muse, mutect2, varscan2
- TTN | c.90063C>A p.V30021= (on ENST00000591111; = p.V22597= on NM_003319.4) | Silent (SNP) | VAF 18/263 reads (7%) | catalogued as COSV59935314; called by muse, mutect2
